Somatic mutation profile of tumor specimen BA2319D (aliquot aq-BA2319D) from BEATAML1.0 case 2078, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Primary myelofibrosis; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,437 days).
Specimen BA2319D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e021715a-6511-4e29-8522-70c4a419d8d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2346D (Solid Tissue Normal), aliquot aq-BA2346D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89735904-c9f5-4d01-8e56-9b6218cea5e5

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPRIN2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 25/152 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs7090312; called by muse, mutect2, varscan2
- ETV6 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.035); catalogued as rs772935596, COSV56765411, COSV56765443; called by muse, mutect2, varscan2
- PCDHA12 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1554168680, COSV56482309; called by muse, mutect2, varscan2
- THSD7A | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as rs765745304, COSV101448644, COSV70264999; called by muse, mutect2, varscan2
